Somatic mutation profile of tumor specimen ALCH-AF1N-TTP1-A (aliquot ALCH-AF1N-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AF1N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 47.3 years (17,268 days).
Specimen ALCH-AF1N-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49c0e116-8e54-46de-b7f8-f1bab684a160.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AF1N-NB1-A (Blood Derived Normal), aliquot ALCH-AF1N-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac26f736-9192-4874-b469-3bfa1570c44b

The open-access MAF lists 63 somatic variants for this specimen: 42 protein-altering or splice-affecting, 13 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 13, Intron 6, RNA 2, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.358A>G p.K120E | Missense Mutation (SNP) | VAF 70/208 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912658, CM921039, COSV52676498, COSV52692352, COSV53551619, COSV53685479; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1373T>C p.M458T (on ENST00000272895 / NM_173076.3; = p.M140T on NM_015657.3) | Missense Mutation (SNP) | VAF 60/695 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs971392004; called by muse, mutect2
- ABCA13 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780007627, COSV70031519; called by muse, mutect2
- ADAMTS16 | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 92/338 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as rs776235298, COSV56977650; called by muse, mutect2, varscan2
- ADAMTS4 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 35/278 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs201261893; called by muse, mutect2, varscan2
- C1QB | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 22/271 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.033); catalogued as rs770317321, COSV59245894; called by muse, mutect2
- CACNA1S | c.4015G>A p.D1339N | Missense Mutation (SNP) | VAF 53/518 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV62945037; called by muse, mutect2, varscan2
- CCDC158 | c.1573C>T p.R525W | Missense Mutation (SNP) | VAF 33/428 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756093518; called by muse, mutect2
- CHST7 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52100886; called by muse, mutect2, varscan2
- CNTNAP2 | c.3919G>A p.A1307T | Missense Mutation (SNP) | VAF 74/661 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.098); catalogued as rs139234992; ClinVar: uncertain significance; called by muse, varscan2
- FAT2 | c.947C>A p.S316Y | Missense Mutation (SNP) | VAF 31/382 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV55823865; called by muse, mutect2
- FBXO41 | c.68C>G p.S23W | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1232150116; called by muse, mutect2, varscan2
- FLNC | c.1885C>T p.R629W | Missense Mutation (SNP) | VAF 25/311 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs759376455; ClinVar: uncertain significance; called by muse, mutect2
- GDF10 | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 57/635 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781954936; called by muse, mutect2
- GJB3 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 49/565 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs147106166; ClinVar: benign; called by muse, mutect2
- HMCN1 | c.8743G>C p.E2915Q | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.644); catalogued as COSV99624892; called by muse, mutect2
- IFT122 | c.817-3C>T | Splice Region (SNP) | VAF 62/707 reads (9%) | catalogued as rs1316687816, COSV99959303, COSV99959455; called by muse, mutect2
- IGF2R | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as rs561986253, COSV63630214; called by muse, mutect2, varscan2
- MUC2 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs780669913; called by muse, mutect2, varscan2
- MYBPH | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 41/530 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548130022, COSV55142576; called by muse, mutect2
- OR2J2 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV101013240; called by muse, mutect2
- PCF11 | c.174C>G p.I58M | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100019487; called by muse, mutect2, varscan2
- PCNX2 | c.3571G>C p.E1191Q | Missense Mutation (SNP) | VAF 22/444 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50784020; called by muse, mutect2
- PLPP3 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs1400216670; called by muse, mutect2
- RADIL | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 49/717 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs756246829, COSV68203067; called by muse, mutect2
- RYR3 | c.3304G>A p.G1102S | Missense Mutation (SNP) | VAF 56/582 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243221135, COSV104430516; called by muse, mutect2
- SMARCC2 | c.648C>G p.I216M | Missense Mutation (SNP) | VAF 49/1748 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV99911457; called by muse, mutect2
- STK3 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 59/293 reads (20%) | catalogued as rs781199889, COSV69221291; called by muse, mutect2, varscan2
- TELO2 | c.2203A>C p.M735L | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.289); catalogued as COSV51977035; called by muse, mutect2, varscan2
- ZNF382 | c.1376C>T p.T459M | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs751264916, COSV99497808; called by muse, mutect2
- ZP4 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 36/307 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs759879282, COSV63912911, COSV99053321; called by muse, mutect2, varscan2
- CD22 | c.908A>G p.Q303R | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.372); called by muse, mutect2
- GLDN | c.1529T>C p.L510S | Missense Mutation (SNP) | VAF 47/470 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- HIVEP1 | c.3929G>C p.S1310T | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCNG1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 61/766 reads (8%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.937); called by muse, mutect2
- LILRB3 | c.144G>C p.W48C | Missense Mutation (SNP) | VAF 52/980 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- LRRC17 | c.167T>C p.V56A | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2
- OSBP2 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, mutect2
- SLC39A9 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 31/472 reads (7%) | called by muse, mutect2
- VN1R4 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 32/435 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2
- WDR36 | c.741A>T p.K247N | Missense Mutation (SNP) | VAF 34/609 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- ZNF648 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.114); called by muse, mutect2
- ANK2 | c.2091A>C p.T697= | Silent (SNP) | VAF 254/899 reads (28%) | called by muse, mutect2, varscan2
- BPIFB2 | c.396C>A p.V132= | Silent (SNP) | VAF 28/372 reads (8%) | called by muse, mutect2
- FZR1 | c.144C>T p.F48= | Silent (SNP) | VAF 11/256 reads (4%) | called by muse, mutect2
- KIF1A | c.2022G>A p.L674= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs373116562; ClinVar: likely benign; called by muse, mutect2, varscan2
- L1CAM | c.2919C>T p.P973= | Silent (SNP) | VAF 33/184 reads (18%) | catalogued as rs375705679, CD099763, COSV62829163; called by muse, mutect2, varscan2
- MAGEB5 | c.300C>T p.V100= | Silent (SNP) | VAF 23/181 reads (13%) | called by muse, mutect2, varscan2
- MEX3B | c.1593G>T p.V531= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as rs1386665700, COSV61663345; called by muse, mutect2
- NHP2 | c.288C>G p.V96= | Silent (SNP) | VAF 64/950 reads (7%) | called by muse, mutect2
- NUP160 | c.2442G>A p.R814= | Silent (SNP) | VAF 14/222 reads (6%) | called by muse, mutect2
- OR52K2 | c.606C>T p.I202= | Silent (SNP) | VAF 35/499 reads (7%) | catalogued as rs569235087, COSV57834566; called by muse, mutect2
- PCDHGA11 | c.567G>A p.G189= | Silent (SNP) | VAF 48/562 reads (9%) | catalogued as COSV53939543; called by muse, mutect2
- TRNAU1AP | c.54C>T p.F18= | Silent (SNP) | VAF 32/454 reads (7%) | catalogued as rs1292176784; called by muse, mutect2
- ZNF365 | c.1119C>T p.L373= | Silent (SNP) | VAF 32/632 reads (5%) | called by muse, mutect2
- AKTIP | c.711-10C>G | Intron (SNP) | VAF 18/308 reads (6%) | called by muse, mutect2
- B3GALNT1 | c.-34-3245A>G | Intron (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- FAM205BP | n.820C>T | RNA (SNP) | VAF 31/358 reads (9%) | catalogued as rs748951322; called by muse, mutect2
- IRF5 | c.481+41G>C | Intron (SNP) | VAF 22/340 reads (6%) | called by muse, mutect2
- LINC01949 | n.955T>G | RNA (SNP) | VAF 13/278 reads (5%) | called by muse, mutect2
- PGA5 | c.657-84C>T | Intron (SNP) | VAF 68/960 reads (7%) | catalogued as rs541455021; called by muse, mutect2
- RIMS2 | c.3821+944G>A | Intron (SNP) | VAF 38/549 reads (7%) | called by muse, mutect2
- SLC16A7 | c.218-3006C>T | Intron (SNP) | VAF 25/205 reads (12%) | catalogued as rs143151350; called by muse, mutect2, varscan2
